Gene-level copy-number profile of tumor specimen TCGA-AB-2856-03A from TCGA case TCGA-AB-2856, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,317 days).
Specimen TCGA-AB-2856-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.17da0ae5-54eb-4f18-8955-d83fb5f51519.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2856-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a9c9086-6f63-45a4-bdcc-d8fc47706c9c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,393; copy number 1: 200; copy number 2: 57,476; copy number 3: 184; copy number 4: 7; copy number 5: 2; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AB-2856-03A-01D-0756-21): tumor purity 0.45, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:36,079,084–36,085,736, 1 gene (within-gene range 0–2): AC083864.1.
- chr10:27,331,357–27,414,368, 6 genes: AL355493.1, RNU6-452P, LINC02673, FAM210CP, TRIAP1P1, PTCHD3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:47,556,731–47,560,259, 1 gene, copy number 7: AC107398.2.
- chr10:3,009,976–3,013,111, 1 gene, copy number 5 (within-gene range 2–5): AL731533.1.
- chr14:22,630,929–22,644,352, 1 gene, copy number 5 (within-gene range 2–5): OR6J1.

Autosomal genes at a single copy (total copy number 1): 200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
